Somatic mutation profile of tumor specimen TCGA-KK-A59Z-01A (aliquot TCGA-KK-A59Z-01A-12D-A26M-08) from TCGA case TCGA-KK-A59Z, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.5 years (24,306 days).
Specimen TCGA-KK-A59Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3abe430a-1f4d-47b5-8c85-ec873f38ad54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A59Z-11A (Solid Tissue Normal), aliquot TCGA-KK-A59Z-11A-11D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17afae63-29f9-4e99-aff1-3465e8a5c41b

The open-access MAF lists 55 somatic variants for this specimen: 47 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 40, Silent 8, Frame Shift Del 2, In Frame Del 2, Frame Shift Ins 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.398T>G p.F133C | Missense Mutation (SNP) | VAF 52/149 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1057519967, COSV61653174, COSV61653874; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARFGEF2 | c.1472G>T p.S491I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64214223; called by muse, mutect2, varscan2
- CAMK2A | c.1415C>T p.A472V (on ENST00000348628 / NM_171825.2; = p.A483V on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.628); catalogued as rs767783317, COSV62245066; called by muse, mutect2, varscan2
- CAPN12 | c.270A>T p.E90D | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.9); catalogued as COSV61017654; called by muse, mutect2, varscan2
- CCDC136 | c.1943G>A p.R648H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs778238940, COSV52798212; called by muse, mutect2, varscan2
- CUL2 | c.1516A>C p.S506R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV66080245; called by muse, mutect2, varscan2
- CYP2C8 | c.177A>C p.K59N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs1281247291, COSV64878383; called by muse, mutect2, varscan2
- DACT1 | c.785A>T p.N262I | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100241719, COSV60022681; called by muse, mutect2, varscan2
- DACT3 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs768322728, COSV56260949; called by muse, mutect2, varscan2
- EPDR1 | c.205T>A p.Y69N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52261274; called by muse, mutect2, varscan2
- FAM216A | c.506C>T p.T169I | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV62195320; called by muse, mutect2, varscan2
- GGT5 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.844); catalogued as rs200655605; called by muse, mutect2, varscan2
- ITGAM | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV54940682; called by muse, mutect2, varscan2
- KDSR | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.074); catalogued as COSV58507695; called by muse, mutect2, varscan2
- KIF19 | c.459C>A p.I153= | Splice Region (SNP) | VAF 36/81 reads (44%) | catalogued as rs781330690, COSV63430260; called by muse, mutect2, varscan2
- KRBA1 | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs532775260; called by muse, mutect2, varscan2
- KRT16 | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV56968675, COSV56969149; called by muse, mutect2, varscan2
- METTL6 | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV101085010, COSV101085061, COSV67542481; called by muse, mutect2, varscan2
- NEPRO | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 90/238 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV58724144; called by muse, varscan2
- OR4A15 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV59033920, COSV59036784; called by muse, mutect2, varscan2
- PALB2 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as rs587778587, CM156713, COSV55163483; ClinVar: likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PCDHGA9 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV54003361; called by muse, mutect2, varscan2
- PLEKHA6 | c.244T>C p.F82L | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55338345; called by muse, mutect2, varscan2
- POU4F2 | c.941C>G p.A314G | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55586125; called by muse, mutect2, varscan2
- PPFIBP1 | c.2240G>T p.G747V (on ENST00000318304 / NM_177444.3; = p.G741V on NM_003622.4) | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57296616; called by muse, mutect2, varscan2
- RSPH14 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); catalogued as COSV53271017, COSV99321181; called by muse, mutect2, varscan2
- RXFP2 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV53638924; called by muse, mutect2, varscan2
- SACS | c.5450C>T p.T1817M | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs898102157, COSV66544937; called by muse, mutect2, varscan2
- SCN10A | c.3766C>T p.R1256W | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs747044382, COSV71861826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs765136101; called by mutect2, pindel, varscan2
- SLC7A5 | c.1034C>T p.T345I | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55366287; called by muse, mutect2, varscan2
- SMARCD2 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs759507599, COSV56741228; called by muse, mutect2, varscan2
- SMTNL2 | c.572G>A p.R191Q (on ENST00000389313 / NM_001114974.2; = p.R47Q on NM_198501.3) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs556796500, COSV58809374; called by muse, mutect2, varscan2
- STAB2 | c.5819G>A p.R1940Q | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs139559759, COSV101185603; called by muse, mutect2, varscan2
- SYNE1 | c.15601G>C p.D5201H (on ENST00000367255 / NM_182961.4; = p.D5130H on NM_033071.3) | Missense Mutation (SNP) | VAF 84/172 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.547); catalogued as COSV55060333; called by muse, mutect2
- SYT10 | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV57343744; called by muse, mutect2, varscan2
- SYT7 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs144496851; called by muse, mutect2, varscan2
- TFDP2 | c.1182T>A p.D394E (on ENST00000489671 / NM_001178139.2; = p.D334E on NM_006286.5) | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV57710160; called by muse, mutect2
- TMEM151A | c.146C>A p.T49K | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV59174662; called by muse, mutect2, varscan2
- TTC39C | c.976C>T p.R326* (on ENST00000317571 / NM_001135993.2; = p.R265* on NM_153211.4) | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as rs754229987, COSV58219853; called by muse, mutect2, varscan2
- TUBA3C | c.1254C>A p.F418L | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68029311; called by muse, mutect2
- WIF1 | c.613C>A p.H205N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV54134411; called by muse, varscan2
- XPO7 | c.461T>G p.I154S | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV53018454; called by muse, mutect2, varscan2
- ADAM28 | c.97_120del p.P33_H40del | In Frame Del (DEL) | VAF 22/67 reads (33%) | called by mutect2, pindel, varscan2
- C11orf1 | c.231_251del p.Y78_V84del | In Frame Del (DEL) | VAF 7/30 reads (23%) | called by mutect2, pindel
- SACS | c.3048_3051del p.L1017Rfs*17 | Frame Shift Del (DEL) | VAF 37/101 reads (37%) | called by mutect2, pindel, varscan2
- URGCP | c.1929dup p.A644Cfs*94 (on ENST00000453200 / NM_001077663.3; = p.A635Cfs*94 on NM_017920.4) | Frame Shift Ins (INS) | VAF 11/100 reads (11%) | called by pindel, varscan2
- CDH16 | c.1272C>T p.G424= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs145180383; called by muse, mutect2, varscan2
- FCGBP | c.2262C>T p.C754= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs183023275; called by muse, mutect2
- LRRFIP1 | c.825A>G p.Q275= (on ENST00000392000 / NM_001137552.2; = p.Q251= on NM_004735.4) | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs1358302767, COSV55254739; called by muse, mutect2
- NOS1 | c.2694C>T p.C898= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as rs375782081; called by muse, mutect2, varscan2
- PIBF1 | c.693A>G p.K231= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV58326798; called by muse, mutect2, varscan2
- SLC24A5 | c.1053C>A p.I351= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV51051005; called by muse, mutect2, varscan2
- SLC7A2 | c.1467G>A p.Q489= (on ENST00000494857 / NM_001370338.1; = p.Q528= on NM_003046.6) | Silent (SNP) | VAF 69/112 reads (62%) | catalogued as COSV50266085; called by muse, mutect2, varscan2
- TYK2 | c.2997G>A p.Q999= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV53390194; called by muse, mutect2, varscan2
